Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A12C, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A12C-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis & History:

y/o female with left breast IDC and DCIS, now for segmental resection and SLNB.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla (fs)
- 2: SP: Sentinel node #2, level 1, left axilla
- 3: SP: Sentinel node #3, level 1, left axilla
- 4: SP: Sentinel node #4, level 1, left axilla
- 5: SP: Left axillary contents levels 1, 2 and 3
- 6: SP: Additional level 3 nodes, left axilla
- 7: SP: Left breast mammographic mass

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1 LEVEL I LEFT AXILLA BIOPSY:
- METASTATIC MAMMARY CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).
- EXTRANODAL EXTENSION IS PRESENT (>2 MM).
- 2) LYMPH NODE, SENTINEL #2 LEVEL I LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1) WITH A TUMOR EMBOLUS IN PERINODAL LYMPHATIC VESSEL.
- 3) LYMPH NODE, SENTINEL #3 LEVEL I LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE, SENTINEL #4 LEVEL I LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) AXILLARY CONTENTS, LEFT LEVELS I, II AND III; DISSECTION:
- LEVEL I: A MICROSCOPIC FOCUS OF METASTATIC MAMMARY CARCINOMA IN ONE OF THREE LYMPH NODES (1/3).
- LEVEL II: EIGHTEEN BENIGN LYMPH NODES (0/18).
- LEVEL III: SIX BENIGN LYMPH NODES (0/6).
- 6) LYMPH NODE, ADDITIONAL LEVEL III LEFT AXILLA; EXCISION:
- BENIGN ADIPOSE TISSUE WITH MICROSCOPIC LYMPHOID AGGREGATES.
- 7) BREAST, LEFT; EXCISION:
- MULTIPLE FOCI OF INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC

** Continued on next page **

100-0-3
carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9 lw 10/23/11

Case ID	100-0-3
Investigator's Name	Dr. [Signature]
Investigator's Title	Pathologist
Primary Tumor Site	Breast
Site Discrepancy	No
Local/Regional History	No
Case is (check):	Primary
Review of Illness	Yes
Unusual	No

[page 2 of 6]
GRADE II-III/III, NUCLEAR GRADE II/III, RANGING IN SIZE FROM 0.1 CM UP TO 2.5 CM (THE TWO LARGEST FOCI OF TUMOR MEASURE 1.4 CM AND 2.5 CM GROSSLY).
- A FEW FOCI OF DUCTAL CARCINOMA IN SITU (DCIS), SOLID AND CRIBRIFORM TYPES WITH INTERMEDIATE NUCLEAR GRADE.

- NO CALCIFICATIONS ARE IDENTIFIED IN EITHER THE INVASIVE OR IN SITU COMPONENT.

- PROMINENT VASCULAR INVASION IS PRESENT.

- INVASIVE CARCINOMA EXTENDS TO THE FOLLOWING SHAVED MARGINS: LATERAL (IN 1/8 SLIDES, 0.6 CM); INFERIOR (IN 3/8 SLIDES, THE LARGEST FOCUS MEASURING 0.8 CM); ANTERIOR (IN 4/19 SLIDES, THE LARGEST FOCUS MEASURING 0.5 CM); AND POSTERIOR (IN 1/15 SLIDES, THE LARGEST FOCUS MEASURING 0.2 CM). IN ADDITION, LYMPHATIC TUMOR EMBOLI ARE ALSO SEEN AT THE MARGINS.

- NO INVOLVEMENT OF THE SURGICAL MARGINS BY DCIS IS IDENTIFIED.

- BIOPSY SITE CHANGES.

- RESULTS OF SPECIAL STAINS (ER, PR, HER-2/NEU) WILL BE REPORTED AS AN ADDENDUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

Comment

RECUT
RECUT
RECUT
RECUT
NEG CONT
IMM RECUT
ER-C
PR-C
HER2-C
NEG-HER2

Gross Description:

1) The specimen is received fresh for frozen section consultation labeled, "Sentinel node #1, level 1, left axilla", and consists of a piece of yellow-tan fatty tissue measuring 3.5 x 2 x 1 cm, containing firm gray lymph node measuring 1.4 x 1 x 0.7 cm. Representative section is frozen. The remainder of the specimen is entirely submitted.

Summary of Sections:

FSC frozen section control

U - undesignated

** Continued on next page **

[page 3 of 6]
2) The specimen is received in formalin, labeled, "Sentinel node #2, level 1, left axilla". It consists of a 0.9 x 0.5 x 0.4 cm tan lymph node with attached adipose tissue. The entire lymph node is submitted.

Summary of Sections:
LN - lymph node

3) The specimen is received in formalin, labeled, "Sentinel node #3, level 1, left axilla". It consists of a 1.3 x 0.4 x 0.3 cm tan lymph node. The lymph node is entirely submitted.

Summary of Sections:
LN - lymph node

4) The specimen is received in formalin, labeled, "Sentinel node #4, level 1, left axilla". It consists of a 0.3 x 0.3 x 0.2 cm tan lymph node with attached adipose tissue. The lymph node is entirely submitted.

Summary of Sections:
LN - lymph node

5) The specimen is received in formalin, labeled, "Left axillary contents levels 1, 2 and 3 (with tags attached)". It consists of a 17.0 x 15.0 x 4.0 cm fragment of adipose tissue with metallic tags labeling levels 1 through 3. Multiple lymph nodes are identified within each level, measuring from 0.2 to 2.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of Sections:
LIBLN level one bisected lymph node
LILNSS level one, one lymph node serially sectioned
LII level two lymph nodes
LIII level three lymph nodes

6) The specimen is received in formalin, labeled, "Additional level 3 nodes, left axilla". It consists of a 2.0 x 1.8 x 1.0 cm aggregate of adipose tissue. No definite lymph nodes are identified. Entirely submitted.

Summary of Sections:
U - undesignated

7) The specimen is received fresh, labeled, "Left breast mammographic mass (short stitch superior, long stitch lateral)". It consists of a 9.5 x

** Continued on next page **

[page 4 of 6]
4

8.0 x 5.3 cm fragment of fibroadipose tissue with a needle localizing wire and sutures marking the superior and lateral margins. The specimen is inked as follows: black-anterior and posterior, yellow-superior, green-inferior, blue-lateral, red-medial. The margins are entirely shaved and submitted. There is a palpable mass at the lateral/inferior portion of the specimen. Serial sectioning reveals a 2.5 x 2.0 x 1.8 cm firm white stellate mass, located in the center of the specimen, closely approaching the anterior margin. Noted adjacent to this mass, near or close to the medial margin is a second tan firm nodular mass, measuring 1.4 x 1.1 x 0.9 cm. The remaining breast parenchyma is predominantly fatty with foci of fibrous tissue. No other lesions are identified. Representative sections are submitted. Portions of both the larger and smaller tumors are submitted for TPS.

Summary of Sections:

M medial
L lateral
I inferior
A anterior
S superior
P posterior
LT larger tumor
ST smaller tumor
ADJ adjacent to tumor mass
RS representative sections

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, left axilla

Block	Sect.	Site	PCs
1	fsc		1
1	u		1

Part 2: SP: Sentinel node #2, level 1, left axilla

Block	Sect.	Site	PCs
1	ln		1

Part 3: SP: Sentinel node #3, level 1, left axilla

Block	Sect.	Site	PCs
1	ln		1

Part 4: SP: Sentinel node #4, level 1, left axilla

Block	Sect.	Site	PCs
1	ln		1

Part 5: SP: Left axillary contents levels 1, 2 and 3 /

Block	Sect.	Site	PCs

** Continued on next page **

[page 5 of 6]
2 LIBLN
5 LII
3 LIII
5 LIIII
LILNSS

4
10
6
5

Page 5 of 6

Part 6: SP: Additional level 3 nodes, left axilla

Block	Sect.	Site	PCs
1	u		1

Part 7: SP: Left breast mammographic mass

Block	Sect.	Site	PCs
19	a		19
2	adj		2
8	i		13
8	l		14
4	lt		4
4	m		10
15	p		15
5	rs		5
4	s		10
2	st		2

Procedures/Addenda:
Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out
By:

Addendum Diagnosis

ADDENDUM REPORT

SITE: LEFT BREAST (PART #7)
ER: 95% NUCLEAR STAINING WITH MODERATE INTENSITY
PR: 40% NUCLEAR STAINING WITH WEAK TO MODERATE INTENSITY
HER-2/NEU (HERCEPT): POSITIVE (STAINING INTENSITY OF 3+)

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

** Continued on next page **

[page 6 of 6]
1) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA.
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file b96d91d9-5bac-458a-bfe7-480ec98e2268 (TCGA-AO-A12C.7E9202F6-F2DB-4CC0-A10F-3D9A82E84242.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).